Somatic mutation profile of tumor specimen MBCProject_1892_T1_WES (aliquot MBCProject_1892_T1_WES_1) from CMI case MBCProject_1892, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 34.3 years (12,534 days).
Specimen MBCProject_1892_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28d138af-4357-4c5a-a1ed-9b56eace1b6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1892_SALIVA (Saliva), aliquot MBCProject_1892_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0e85ecb-e202-4896-92ec-060779a06628

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Frame Shift Del 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DAB2IP | c.2801G>A p.R934Q (on ENST00000408936; = p.R906Q on NM_032552.3) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.55); catalogued as rs777357265; called by muse, mutect2, varscan2
- FANK1 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV64156341; called by muse, mutect2
- JPH2 | c.822C>A p.D274E | Missense Mutation (SNP) | VAF 49/1354 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0.092); catalogued as rs1385874818, COSV65904961; called by muse, mutect2
- SERPINB8 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 41/342 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.104); catalogued as rs758705957, COSV54640588; called by muse, mutect2, varscan2
- SLC6A18 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs148359610, COSV57252552; called by muse, varscan2
- TGFB1I1 | c.1004G>T p.R335L (on ENST00000394863 / NM_001042454.3; = p.R318L on NM_015927.4) | Missense Mutation (SNP) | VAF 57/592 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV62357120; called by muse, mutect2, varscan2
- UNC93B1 | c.1633G>T p.D545Y | Missense Mutation (SNP) | VAF 43/679 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs557919554; called by muse, mutect2
- XKR4 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 31/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs931462398, COSV59311222; called by muse, mutect2
- ANK2 | c.11268A>C p.K3756N | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- BFSP1 | c.67C>A p.R23S | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.109); called by muse, mutect2
- GATA3 | c.1219dup p.S407Ffs*100 | Frame Shift Ins (INS) | VAF 129/669 reads (19%) | called by mutect2, pindel, varscan2
- ISOC2 | c.575G>A p.G192E (on ENST00000425675 / NM_001136201.2; = p.G208E on NM_024710.3) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NOL10 | c.1320_1321del p.R440Sfs*10 | Frame Shift Del (DEL) | VAF 12/109 reads (11%) | called by pindel, varscan2
- PGR | c.498C>A p.S166R | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.447); called by muse, mutect2
- PPP6R3 | c.134_135del p.I45Rfs*26 | Frame Shift Del (DEL) | VAF 157/486 reads (32%) | called by pindel, varscan2
- GABRB3 | c.651T>A p.R217= | Silent (SNP) | VAF 26/740 reads (4%) | called by muse, mutect2
- OLIG2 | c.147G>A p.P49= | Silent (SNP) | VAF 14/277 reads (5%) | catalogued as rs1256976546; called by muse, mutect2
- PGBD1 | c.534G>A p.G178= | Silent (SNP) | VAF 39/230 reads (17%) | called by muse, mutect2, varscan2
- SORBS1 | c.2129-1279dup | Intron (INS) | VAF 45/275 reads (16%) | called by mutect2, pindel, varscan2
